Surgical pathology report (de-identified scan), TCGA case TCGA-4E-A92E, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Molecular Response, specimen TCGA-4E-A92E-01A (Primary Tumor).

[page 1 of 6]
Site ID

Subject Number:

Please complete ALL information with black ball point pen. Ensure information is legible.
Retain original and email/fax copy to

Sample Collection Date:	D D - M M - Y Y Y Y	Procured by: _____
Time of Tumor Sample Excision (24 hour clock):	H H : M M	Time Zone: _____
TUMOR-FROZEN & FRESH SAMPLES FROZEN SAMPLES BATCH SHIPPED (dry ice); FRESH TUMOR SAMPLE, IF COLLECTED, SHIPPED ON DAY OF COLLECTION		
Collect resected tumor in accordance with standard procedures. Weigh the sample and section off ~100mg. Frozen Tumor (Required) Place this sample in the cryovial labeled Frozen Tumor sample and record the weight. Place the cryovial in a can and then into the vapor phase dewar. Record the time placed in dewar.		
Weight of Tissue: 240 mg (tissue weight must be ≥ 100mg)	Time placed in dewar: (24 hour clock)	H H : M M
Fresh Tumor (Optional) ☐ N/A Locate the "Fresh Tumor" label in the kit and affix to the 15ml tube (sent separately). Place any remaining tumor tissue into the 15ml conical tube containing		
Weight of Tissue: 140 mg (no min. weight specified)	Time placed in (24 hour clock)	Lot Number of H H : M M
WHOLE BLOOD SAMPLE (Required) - BATCHED SHIPPED FROZEN (dry ice)		
Sample Collection Date:	D D - M M - Y Y Y Y	Procured by: _____
Time of Blood Sample Collection (24 hour clock):	H H : M M	Time Zone: _____
1-10ml EDTA tube. Fill tube completely and mix by gentle inversion at least 8-10 times. Freeze sample on dry ice or place in vapor phase dewar.		
Time placed in dry ice/dewar: (24 hour clock) H H : M M		
BASIC PATHOLOGICAL INFORMATION		
Clinical Diagnosis: (Ex. Lung Cancer)	Endometrial Cancer	Source of Specimen: (Ex. Right Lung) Endometrial Sal

Confidential
Valid from

ICD-C-3
Adenocarcinoma, endometrial NOS
Site Endometrium
C54.1
Jt 3/26/14

[page 2 of 6]
Confidential

Tissue/Blood Requisition Form

Affix Label Here
Or Write in Sample ID

Site ID:

Subject Number:

Diagnostic Slides (Required) - SLIDES BATCHED SHIPPED (ambient)

From the diagnostic FFPE block, cut 3 slides with one section ~ 4-5µm on each slide. Label the frosted tip of the slide in pencil with the sample ID (located on the label at the top of this form). Record the ID number of the diagnostic histology cassette and the number of slides. H&E stain the slides and store in a slide mailer.

Diagnostic Histology Cassette ID

Number of Slides Cut 3

Refer to **Study Manual for detailed specimen processing and shipping instructions.** (* denotes required samples)

Specimen	Collection Vessel	Transfer Tube	Shipping Status
Frozen Tumor*	None	Cryovial	Same Day – Dry Ice
Frozen Blood*	1-10ml EDTA	None	Same Day – Dry Ice
Fresh Tumor	None	15ml-	Same Day – Refrigerated
Diagnostic Slides*	Histology Cassette	SuperFrost Slides	5-Slide Mailer—Batch

When FROZEN and FRESH samples are ready for shipment please notify by Email notification:
At this time, please also provide your Sample Manifest.

When the Diagnostic slides are ready for shipment please notify by Email notification: At this time, please also provide your Sample Manifest.

DO NOT RETURN EMPTY CONTAINERS TO

White copy-Retain for your Records

Yellow copy-send to pathology for diagnostic slides

[page 3 of 6]
Surg Path Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

* Final Report *

Final Diagnosis (Verified)

Uterus and cervix with bilateral fallopian tubes and ovaries, resection:

Well-differentiated adenocarcinoma (endometrioid type, FIGO grade 1), confined to endometrium.

There is no evidence of tumor invasion into underlying myometrium in the examined sections and no evidence of lymphovascular invasion.

Focal adenomyosis.

Leiomyomas.

Benign cervical tissue with no evidence of neoplasm.

Benign parauterine tissue.

Benign fallopian tubes and ovaries.

Left external iliac lymph nodes, excision:

Benign adipose tissue.

No lymphoid tissue is present for evaluation.

Left internal iliac lymph nodes, excision:

Benign fibroadipose tissue.

No lymphoid tissue is present for evaluation.

Left aortic lymph nodes, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Right external iliac lymph nodes, excision:

One (1) benign lymph node with no evidence of metastatic neoplasm.

Right internal iliac lymph nodes, excision:

[page 4 of 6]
Surg Path Final Report

* Final Report *

Benign fibroadipose tissue.
Lymphoid tissue is not present for evaluation.

Right obturator lymph nodes, excision:
Two (2) benign lymph nodes with no evidence of metastatic neoplasm.

Right common iliac lymph nodes, excision:
Benign fibroadipose tissue.
Lymphoid tissue is not present for evaluation.

Right aortic lymph nodes, excision:
Two (2) benign lymph nodes with no evidence of metastatic neoplasm.

Comment: AJCC pathologic stage: T1a,N0.

Gross Description (Verified)

"A. Uterus, cervix, bilateral tubes, and ovaries." The specimen consists of a 53 gram, 7.2 x 3.6 x 3.5 cm previously bivalved uterus with attached cervix. The serosa is pink-tan with rare adhesions. The ectocervix is pink-tan to red-tan, smooth and glistening, and averages 3.1 x 2.6 cm. The os is patent. The cervical neck is inked as follows: anterior cervical neck orange and posterior cervical neck black. Previous opening reveals a pink-tan, soft, friable mass involving the superior endometrium. This has an overall measurement of 1.7 cm superior to inferior, 1.5 cm left to right, and 0.9 cm anterior to posterior. This mass grossly appears to predominantly involve the anterior endometrium. This mass grossly appears to be confined to the inner one-half aspect of the myometrium and comes to within 0.8 cm of the anterior serosa. The remaining endometrium is pale tan and averages less than a millimeter in thickness. The myometrium averages 1.4 cm in thickness. There are less than five (5) intramural nodules measuring up to 0.7 cm. On sectioning, these have gray-white, whorled cut surfaces. Attached to the uterus is the left fallopian tube with fimbriae, which measures 4.5 x 0.4 cm. Adherent to the tube is a 0.3 cm thin-walled, yellow-tan, serous fluid-filled cyst. There is also an attached left ovary, which measures 2.0 x 1.5 x 0.7 cm. On sectioning, there is a 0.5 cm white-tan, corpus albicans. The remaining cut surface is pink-tan and solid. Attached to the uterus is the right fallopian tube with fimbriae, which measures 5.8 x 0.4 cm. Adherent to the fimbriae is a 0.4 cm thin-walled clear fluid-filled paratubal cyst. There is also an attached right ovary.

[page 5 of 6]
Surg Path Final Report

* Final Report *

which measures 2.7 x 1.0 x 0.7 cm. On sectioning, there is a 0.6 cm white-tan corpus albicans. The remaining cut surface is pink-tan and solid. "A1," left parauterine vessels; "A2," right parauterine vessels; "A3," anterior cervix and cervical canal; "A4-A6," anterior endometrium; "A7," posterior cervix and cervical neck; "A8-A10," posterior endometrium; "A11," intramural nodules; "A12," left tube and ovary; "A13," right tube and ovary, representative.

"B, Left external iliac." The specimen consists of a 3.7 cm yellow-tan, fatty fragment. On examination, definite lymphoid tissue is not identified. All tissue is submitted into cassettes "B1-B2."

"C, Left internal iliac." The specimen consists of a 2.3 cm yellow-tan, fatty fragment. On examination, definite lymphoid tissue is not identified. All tissue is submitted into cassette "C."

"D, Left aortic." The specimen consists of a 3.2 cm yellow-tan, fatty fragment. On examination, a 1.1 cm possible on is identified. All lymphoid tissue is submitted into cassette "D," representative.

"E, Right external." The specimen consists of two (2) yellow-tan, fatty fragments measuring 3.1 and 3.3 cm. On examination, a 2.0 cm possible lymph node is identified. A representative section is submitted into cassette "E."

"F, Right internal." The specimen consists of a 1.4 cm yellow-tan, fatty fragment. On examination, definite lymphoid tissue is not identified. All tissue is submitted into cassette "F."

"G, Right obturator." The specimen consists of two (2) yellow-tan, fatty fragments measuring 2.2 and 5.6 cm. On examination, two (2) possible lymph nodes are identified. These measure 1.6 and 4.2 cm. Representative sections are submitted into cassette "G."

"H, Right common iliac." The specimen consists of a 2.1 cm yellow-tan, fatty fragment. On examination, definite lymphoid tissue is not identified. All tissue is submitted into cassette "H."

"I, Right aortic." The specimen consists of a 2.0 cm yellow-tan, fatty fragment. On examination, two (2) possible lymph nodes are identified. These measure 1.0 and 1.1 cm. Representative sections are submitted into cassette "I."

Clinical Information (Verified)

Uterine cancer.

[page 6 of 6]
Non-Gyn Final Report

* Final Report *

Result Type:
Result Date:
Result Status:
Result Title:
Verified By:
Encounter info:

* Final Report *

Comment (Verified)
Scant cellularity.

Diagnosis (Verified)
Negative for neoplastic cells.

Specimen Description (Verified)
Pelvic Washing
40 cc's of bloody fluid/material received in a cup.
Processed by

Clinical Information (Verified)
uterine cancer

Printed by:
Printed on:

Page 1 of 1
(End of Report)

Source: NCI Genomic Data Commons file e4a01f8c-8b31-4eb4-a331-4a3b3ffaad9e (TCGA-4E-A92E.BC43D6CA-235C-4217-BF72-F33B089C532B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).